Surgical pathology report (de-identified scan), TCGA case TCGA-KS-A41J, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Of Michigan, specimen TCGA-KS-A41J-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: [REDACTED]
NAME: [REDACTED]
BIRTHDATE: [REDACTED]

PATIENT NBR: [REDACTED]
PAT TYPE: [REDACTED]

SEX: [REDACTED]
ADM DATE: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE: [REDACTED]

REQ DOC: [REDACTED]

PROCEDURE: SPHS

VERIFIED BY: [REDACTED]

Patient is a [REDACTED]-year-old [REDACTED] with left thyroid nodule, picked up on a
routine physical exam. Left thyroid nodule. Total thyroidectomy.

PROCEDURE: SPGD

VERIFIED BY: [REDACTED]

1. "Left level VI lymph node" Two, 0.4 cm diameter and 0.7 cm diameter tan-red bits of tissue. Entirely submitted.
2. "Total thyroid" A 17.6 gram, 4.5 x 7.2 x 4.2 cm total thyroidectomy with isthmus. The parenchyma is beefy-red-brown with a grossly lobulated appearance. There is a single, 2.3 x 2.1 x 1.8 cm nodule within the left lower lobe of the gland. This nodule approaches to within 0.2 cm of the inked surface. This nodule is well-encapsulated and does not infiltrate the adjacent unremarkable beefy red-brown parenchyma. The nodule is soft, fleshy pink-tan and without areas of hemorrhage or necrosis. Left half of the specimen inked black and right half of specimen inked blue and specimen serially sectioned. Representative sections submitted as follows:
2A.-C. Left lobe nodule with entire capsule.
2D. Isthmus.)
2E.&F. Right lobe.

1C003
Carcinoma, papillary, thyroid
826013

Site: thyroid, NOS
73.9 7-23-12
RD

PROCEDURE: SPDX

VERIFIED BY: [REDACTED]

1. Lymph node, left level VI, excision: Two of two lymph nodes positive for metastatic carcinoma, consistent with papillary thyroid carcinoma.
2. Total thyroid, thyroidectomy: Papillary thyroid carcinoma, closely approximating inked margin, in background of lymphocytic thyroiditis.

I, [REDACTED] the signing staff pathologist, have personally
examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Reviewer Initials: [REDACTED] Date Reviewed: 7/2/12		

Source: NCI Genomic Data Commons file 22aaeab7-2fd4-49e5-ac97-97591524d0c9 (TCGA-KS-A41J.85C21DA8-13C6-4E22-939C-579C38A14891.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).